Surgical pathology report (de-identified scan), TCGA case TCGA-24-2024, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2024-01A (Primary Tumor).

[page 1 of 5]
OF SURGICAL PATHOLOGY

Name:
Address:
MR No.:
Service:
Surgeon:

Surg. Path. No.:
DOB:
Sex/Race:
Location:
Hosp. No.:
Taken/Received:

TCGA-24-2024

DIAGNOSIS

OVARY, RIGHT, SALPINGO-OOPHORECTOMY - POORLY DIFFERENTIATED
PAPILLARY SEROUS ADENOCARCINOMA (SEE COMMENT)

OVARY, RIGHT, "TUMOR," EXCISION - POORLY DIFFERENTIATED PAPILLARY
SEROUS ADENOCARCINOMA

OVARY, LEFT, SALPINGO-OOPHORECTOMY - METASTATIC PAPILLARY SEROUS
CARCINOMA IN PARA-OVARIAN ADHESIONS
- SEROUS CYSTADENOMA

FALLOPIAN TUBE, LEFT, SALPINGO-OOPHORECTOMY - METASTATIC PAPILLARY
SEROUS ADENOCARCINOMA IN PERITUBAL TISSUE

APPENDIX, APPENDECTOMY - METASTATIC PAPILLARY SEROUS
ADENOCARCINOMA INVOLVING THE SEROSAL SURFACE OF APPENDIX

OMENTUM, OMENTECTOMY - METASTATIC PAPILLARY SEROUS ADENOCARCINOMA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- MILD ACUTE AND CHRONIC INFLAMMATION

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- INACTIVE ENDOMETRIUM (SEE COMMENT)

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- LEIOMYOMAS, HYALINIZED, LARGEST
MEASURING 1.9 CM IN GREATEST DIMENSION
- ADENOMYOSIS

UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY - METASTATIC
PAPILLARY SEROUS ADENOCARCINOMA IN SEROSAL ADHESIONS

[page 2 of 5]
[REDACTED]

[REDACTED]

OF SURGICAL PATHOLOGY

Name: [REDACTED]

Surg. Path. No. [REDACTED]

SPECIMEN(S) SUBMITTED

- Part 1: RIGHT OVARY
- Part 2: RIGHT OVARY TUMOR
- Part 3: LEFT OVARY
- Part 4: UTERUS, CERVIX
- Part 5: MESO-APPENDIX
- Part 6: OMENTUM

HISTORY

The patient is a [REDACTED] with an ovarian neoplasm with tumor extending to omentum on CT scan. Increased CA 125. Rule out ovarian carcinoma. Operative procedure: Examination under anesthesia, laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy, omentectomy. An intraoperative non-microscopic consultation was obtained and interpreted as: "Right ovary, ovary measuring 10 x 7 x 6 cm with a 6 x 3 cm area on the external surface with smooth serosa. The surface is replaced by a friable papillary tumor. The majority of the specimen is cystic and contains brown-gray liquid with numerous papillary lesions in the wall. Tumor removed in ER for [REDACTED]"

GROSS

The specimens are received in six containers of formalin, each labeled with the patient's name. The first container is labeled "uterus, cervix" and contains a uterus with cervix weighing 184 grams and measuring 11 x 7.2 x 5.5 cm in greatest dimensions. Externally, the uterine serosa is irregular at the regions of the peritoneal reflection. The rest of the serosa appears hemorrhagic. The uterus is distorted by multiple myomas giving it a multinodular architecture. The os is slit-shaped measuring 1.1 cm in greatest dimensions. The cervical canal measures 4 cm in length. No nodularities or papillary areas are recognized. The endometrial cavity measures 3.7 x 1.3 cm in greatest dimensions. There appears to be a polypoid structure seen on the posterior superior wall of the endometrium. This polypoid structure measures 1.2 x 0.7 cm. The myometrium has a maximum thickness that measures 3 cm. It is distorted by multiple myomas ranging in

[page 3 of 5]
[REDACTED]

[REDACTED]

OF SURGICAL PATHOLOGY

Name: [REDACTED]

Surg. Path. No.:

GROSS (continued)

size from 0.3 to 1.9 cm. These myomas do not appear to show any evidence of cystification, necrosis, or hemorrhage. Some of these are hyalinized and calcified. Occasional subserosal myomas are also recognized. Labeled: C1, anterior cervix; C2, posterior cervix; E1, polypoid area; E2, anterior endomyometrium; E3, posterior endomyometrium; M1 and M2, leiomyomas. Jar 2. [REDACTED]

The second container is labelled "right ovary." It contains a previously sectioned ovary measuring 10 x 7 x 6 cm and weighing 99 grams. The external surface is blue-tan and glistening in areas, but a large area of the surface shows a papillary friable mass measuring 5.5 x 4 cm. No distinct fallopian tube is recognized. The opened surface of the ovary shows a thickened wall in multiple areas with a unilocular cystic structure having multiple papillary friable excrescences. The cut surface in areas shows a somewhat cystic underlying friable tissue. Sections taken and labelled as follows: RO1-RO8, cyst wall; RO7 and RO8, papillary areas from the external surface. Jar 2.

The third container is labelled "right ovary tumor." It contains a large fragment measuring 3 x 3.5 x 1.2 cm in greatest dimensions. This fragment is extremely friable having a papillary configuration. Labelled RO9 and RO10. Jar 1.

The fourth container is labelled "left ovary." It contains a ovary with attached fallopian tube. The ovary measures 3 x 2 x 1.1 cm in greatest dimensions. Externally, each shows multinodular white-yellow configuration with a irregular papillary area seen on one external aspect. The fallopian tube attached measures 5 cm in length having a diameter of 0.9 cm and appears free of tumor. The cut surface of the ovary shows a large cystic cavity filled with serous fluid, unilocular having a smooth lining. Sections taken and labelled: LO1, cyst of the ovary; LO2, fallopian tube; LO3, papillary area. Jar 1.

The fifth container is labelled "mesoappendix." It contains an appendix with attached yellow periappendiceal fat and separate fragment in the same container of yellow fibrofatty tissue. The appendix measures 7 cm in length having a diameter of 0.5 cm in the upper third and 0.6 cm in the middle third and 0.9 cm in the

[page 4 of 5]
[REDACTED]

[REDACTED]

OF SURGICAL PATHOLOGY

Name: [REDACTED]

Surg. Path. No.:

GROSS (continued)

lower third. There appears to be a hemorrhagic nodular area seen in the lower third of the appendix. The attached fibrofatty fragment measures 3.5 x 1.5 x 0.2 cm. It appears unremarkable. The separately submitted fibrofatty fragment measures 3.5 x 1.5 x 0.9 cm. Taken and labelled as follows: A1, appendix; A2, fat. Jar 1.

The sixth container is labelled "omentum." It contains a large fragment of hemorrhagic yellow lobular omental tissue measuring 13 x 9 x 2.5 cm in greatest dimensions. The omentum is completely covered in ~70% of the area by a papillary friable tumor. Representative section taken and labelled B. Jar 2. [REDACTED]

COMMENT

Poorly differentiated papillary serous adenocarcinoma completely replaces the right ovary and is present on the surface of the right ovary. The right fallopian tube is not identified and may have been completely replaced by adenocarcinoma. Small implants of papillary serous adenocarcinoma are present in peritubal tissue in the left fallopian tube and within adhesions in the left ovary. Metastatic papillary serous adenocarcinoma also involves the serosal surface of the appendix and the omentum. The endometrium is atrophic. The polypoid lesion described grossly represents a hyalinized submucosal leiomyoma. Numerous hyalinized leiomyomas and adenomyosis are present in the myometrium. The serosal surface of the uterus also contains metastatic papillary serous carcinoma. [REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

- 1a. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma [REDACTED]
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Right and left ovary [REDACTED]
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated) [REDACTED]
6. Tumor IS identified on the ovarian surface(s). [REDACTED]
7. Tumor DOES invade the mesovarium. [REDACTED]

[page 5 of 5]
[REDACTED]

[REDACTED]

OF SURGICAL PATHOLOGY

Name: [REDACTED]

Surg. Path. No. [REDACTED]

COMMENT (continued)

8. Invasion of adjacent fallopian tube CANNOT BE EVALUATED.
9. Tumor DOES invade the pelvic soft tissue. [REDACTED]
10. Tumor involvement of the pelvic peritoneum is PRESENT.
11. Metastatic involvement of the EXTRAPELVIC peritoneum CANNOT BE EVALUATED. [REDACTED]
12. Metastatic involvement of the omentum is PRESENT. [REDACTED]
14. Metastatic involvement of the uterine serosa is PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases CANNOT BE EVALUATED.
17. The total number of regional lymph nodes examined is 0. [REDACTED]
19. DETAILED STAGING INFORMATION:
Based on the above information, the PRIMARY TUMOR is classified as:

TNM SCHEME	FIGO SCHEME	DEFINITION
T3c	IIIC	Macroscopic peritoneal metastasis beyond true pelvis measuring greater than 2 cm in greatest dimension, OR Regional lymph node metastasis OR Metastasis to capsule of liver. [REDACTED]

THE REGIONAL LYMPH NODES are classified as:
NX (Nodal status cannot be assessed) [REDACTED]
THE STATUS OF DISTANT TUMOR SITES is classified as:
MX (Status cannot be assessed) [REDACTED]

20. The FINAL AJCC/FIGO STAGE requires clinical correlation.

{End of Report}

[REDACTED]

[REDACTED]

GROSS Pathologist [REDACTED]

Source: NCI Genomic Data Commons file d67aa776-24b9-4cf2-8819-54ff9c02a5d6 (TCGA-24-2024.4189CFA0-00C3-42FB-91B9-D2F4B4887061.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).